Somatic mutation profile of tumor specimen HTMCP-03-06-02173-01A (aliquot HTMCP-03-06-02173-01A-01D-6194) from CGCI case HTMCP-03-06-02173, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 39.3 years (14,339 days).
Specimen HTMCP-03-06-02173-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57ed4a10-4ea1-4477-b0fd-4cf44ac6d751.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02173-10A (Blood Derived Normal), aliquot HTMCP-03-06-02173-10A-01D-6194; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e652f5fc-6778-435f-8787-d7d203dee3e5

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP44 | c.1417A>G p.I473V | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs376875025; called by muse, mutect2, varscan2
- EPHB1 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.557); catalogued as rs200018500, COSV67665974; called by muse, mutect2, varscan2
- KDR | c.2695G>A p.V899I | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55758621; called by muse, mutect2
- TTN | c.41551G>A p.A13851T (on ENST00000591111; = p.A6427T on NM_003319.4) | Missense Mutation (SNP) | VAF 17/149 reads (11%) | PolyPhen possibly damaging (0.675); catalogued as rs1370664332; called by muse, mutect2, varscan2
- ADGRL2 | c.3598C>T p.P1200S | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- E2F8 | c.1547_1556del p.P516Hfs*16 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, varscan2
- PHKB | c.2393del p.P798Hfs*13 | Frame Shift Del (DEL) | VAF 11/104 reads (11%) | called by mutect2, pindel
- PMFBP1 | c.1755G>T p.Q585H (on ENST00000537465; = p.Q580H on NM_031293.3) | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.465); called by muse, mutect2
- SYNE2 | c.12441C>G p.D4147E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP3K12 | c.84G>A p.K28= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- TCHHL1 | c.1368C>T p.H456= | Silent (SNP) | VAF 35/281 reads (12%) | called by muse, mutect2, varscan2
- ALDH4A1 | c.678+456G>C | Intron (SNP) | VAF 10/67 reads (15%) | catalogued as rs746090442, COSV99311663; called by muse, mutect2, varscan2
